CCDI case PBCCXW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a8caa8c8-384b-4735-b4d9-251c1fcfa005

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.3 years (6,321 days).

Biospecimens (3 samples)
- Sample 0DP4P0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP4PE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP4Q3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
